Gene-level copy-number profile of tumor specimen ALCH-AE4S-TTP1-A from ALCHEMIST case ALCH-AE4S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.7 years (21,090 days).
Specimen ALCH-AE4S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2f6979fd-6244-486e-ad8d-8397badc130b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE4S-NB1-B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/76d20f23-c397-4e2c-8616-edd52a77193a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 7,842; copy number 2: 49,224; copy number 3: 1,295; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,625,997–127,626,848, 1 gene (within-gene range 0–2): AC010976.2.
- chr2:127,645,864–127,652,639, 1 gene (within-gene range 0–2): GPR17.
- chr5:177,086,905–177,098,144, 1 gene: FGFR4.
- chr10:132,181,225–132,185,962, 1 gene (within-gene range 0–2): AL512622.1.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr17:39,737,927–39,747,291, 1 gene: GRB7.
- chr20:30,484,925–30,816,274, 4 genes: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.
- chr22:18,533,646–18,625,289, 6 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.
- chr22:19,756,703–19,783,593, 1 gene (within-gene range 0–1): TBX1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,984,522, 1 gene, copy number 7 (within-gene range 3–7): MRPL23.

Autosomal genes at a single copy (total copy number 1): 5,521. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
